CPTAC case C3N-03080 — Bronchus and lung — Adenomas and Adenocarcinomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Adenomas and Adenocarcinomas; Primary site: Bronchus and lung. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/b5ecafc8-1af5-4df8-ae50-ad9eb47438e8

Demographics
Sex at birth: male; Race: asian; Year of birth: 1950; Vital status: Dead; Days to death: 847 days (2.3 years); Year of death: 2020; Country of birth: China.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; Tissue or organ of origin: Lung, NOS; Site of resection or biopsy: Lower lobe, lung; Age at diagnosis: 68.0 years (24,834 days); Year of diagnosis: 2018; AJCC staging edition: 8th; AJCC clinical M: M0; AJCC pathologic T: T2b; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIA; Tumor grade: G3; Residual disease: R0; Last known disease status: Tumor free; Days to last known disease status: 847 days (2.3 years); Progression or recurrence: no; Days to last follow up: 740 days (2.0 years); Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 4.8 cm (a second GDC size field records 3 cm); Lymph node involvement: Negative; Lymph nodes positive: 0; Lymph nodes tested: 18; Margin status: Uninvolved.

Follow-up (3 entries)
- Days to follow up: 301 days; Disease response: Tumor Free; Karnofsky performance status: 90; ECOG performance status: 1.
- Days to follow up: 740 days (2.0 years); Disease response: Tumor Free; Karnofsky performance status: 0; ECOG performance status: 5.
- Days to follow up: 740 days (2.0 years); Disease response: Tumor Free; Karnofsky performance status: 100; ECOG performance status: 0.

Other clinical attributes
- Weight: 56 kg; Height: 161 cm; BMI: 21.6; DLCO (% of predicted): 86; FEV1/FVC before bronchodilator (%): 85.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker; Alcohol history: Yes; Alcohol intensity: Not Heavy Drinker.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3N-03080-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 425 mg; Time between clamping and freezing: 26 minutes; Time between excision and freezing: 14 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3N-03080-22: Section location: Right Lower Lobe; Percent tumor nuclei: 80; Percent necrosis: 5.
- Sample C3N-03080-03: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 262 mg; Time between clamping and freezing: 26 minutes; Time between excision and freezing: 14 minutes; Method of sample procurement: Surgical Resection; Diagnosis pathologically confirmed: Yes.
- Sample C3N-03080-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: 0 days; Method of sample procurement: Blood Draw.
